Surgical pathology report (de-identified scan), TCGA case TCGA-06-A5U0, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Henry Ford Hospital, specimen TCGA-06-A5U0-01A (Primary Tumor).

[page 1 of 4]
Surgical Pathology Report

Patient Name: Phone #: Accession #:
Med. Rec. #: Client: Taken:
DOB: Location: Received:
Gender: F Acct: Reported:
Physician(s):

CCF ICD-O-3
Glioblastoma, medulla
9440/3
path Glioblastoma NOS
9440/3
Site: ② Brain, occipital
lobe C71.4
JW 4/18/13

Clinical History

A -year-old woman presented with headaches and right-sided vision loss. Radiology imaging demonstrated a mass in the left occipital lobe, with irregular areas of contrast-enhancement.

Operative Diagnoses

Operation / Specimen

- A: Brain, left occipital, biopsy
- B: Brain, left occipital, biopsy
- C: Brain, left occipital, biopsy

Pathologic Diagnosis

A, B, C. Brain, left occipital, craniotomy:

1. Glioblastoma WHO grade 4
2. Negative for co-deletion of chromosomal arms 1p and 19q
3. Negative for mutant IDH1-R132H protein by immunostain
4. Ki-67/ MIB-1 proliferation index: up to approximately 15%

Electronically Signed Out

Consultant:

Senior Staff Pathologist
Senior Staff Pathologist

Procedures/Addenda

Loss of Heterozygosity 1p, 19q Assay (LOH)

Date Ordered: Date Reported:

Interpretation

POSITIVE: Allelic loss on chromosome arm 1p is detected.

No evidence of LOH of chromosome arm 19q detected.

Informative loci are: D1S1592, D1S468, D1S1612, D19S219, D19S412, PLA2G4C, D19S606

Results-Comments

Surgical Pathology

Page 2 of 5

Testing performed on DNA extracted from tumor paraffin block

(C1). DNA extracted from

a

corresponding blood specimen was used as a normal reference control.

H and E slide was examined and no microdissection was needed.

TEST DESCRIPTION: Allelic loss is assessed by PCR assay in Normal DNA (baseline)/ Tumor DNA pairs using 3

markers at both 1p and 19q. The 3 markers on 1p are D1S548, D1S1592, and D1S552 (with D1S468, D1S1612, and

D1S496 as backup markers) and the 3 markers on 19q are D19S219, D19S412, and PLA2G4C (with D19S606 and

D19S1182 as backup). All markers are microsatellites (2 or 4 nt repeats) except PLA2G4C which is a minisatellite (26

nt repeat) polymorphism. The markers were selected based on heterozygosity score, amplicon size, and ease of

interpretation. The backup markers are used if the first line markers at that chromosome arm are uninformative or

otherwise ambiguous in their interpretation. LOH at all informative loci on each chromosomal arm represents the

typical finding in oligodendrogliomas with 1p and 19q deletion.

[page 2 of 4]
FDA COMMENT: The above data are not to be construed as the results from a stand-alone diagnostic test. This test was developed and its performance characteristics determined by the as required by CLIA '88 regulations. It has not been cleared or approved for specific uses by the U.S. Food and Drug Administration (FDA). The FDA has determined that such clearance or approval is not necessary. These results are provided for informational purposes only, and should be interpreted only in the context of established procedures and/or diagnostic criteria.

TECHNICAL SENSITIVITY: The presence of >15% non-neoplastic cells in the sample may preclude the detection of allelic loss.

Electronically Signed Out

Senior Staff Pathologist

MGMT Promoter Methylation

Date Ordered: **Date Reported:**

Interpretation

POSITIVE: Methylated MGMT promoter is detected.

Results-Comments

Testing performed on DNA extracted from tumor paraffin block (C1).
H and E slide was examined and no microdissection was needed.

TEST DESCRIPTION: Patients with glioma containing a methylated MGMT promoter have been shown to benefit

from therapy with alkylating agents. Assessment of MGMT promoter methylation status involves bisulfite treatment of

DNA followed by real-time PCR amplification of methylated and unmethylated DNA sequences. The

analytic sensitivity of this assay was determined by serial dilution of methylated positive control DNA into unmethylated DNA, and was assessed to be 1% of methylated DNA in the background of unmethylated DNA. Factors

such as the presence of >50% non-neoplastic cells in the sample, or extensive tissue necrosis, may preclude the

detection of methylated MGMT promoter sequences.

FDA COMMENT: The above data are not to be construed as the results from a stand alone diagnostic test. This test

was developed and its performance characteristics determined by the as required

by CLIA '88 regulations. It has not been cleared or approved for specific uses by the U.S. Food and Drug Administration (FDA). The FDA has determined that such clearance or approval is not necessary. These results are

provided for informational purposes only, and should be interpreted only in the context of established procedures

and/or diagnostic criteria.

Surgical Pathology

Page 3 of 5

Electronically Signed Out

Senior Staff Pathologist

IDH1 Mutation Detection Assay

Date Ordered: **Date Reported:**

Interpretation

NEGATIVE - There is no evidence of IDH1 point mutation, as indicated by the absence of any nucleotide changes in

codon 132 of the IDH1 gene compared to the electropherogram of the reference normal sample (wild type).

Results-Comments

[page 3 of 4]
TEST DESCRIPTION: IDH1 Mutation Analysis

Test performed on DNA extracted from tumor paraffin block (C1)

H and E slide was examined and no microdissection was needed.

Mutation of IDH1 occurs early in glioma progression with somatic mutations of the R132 residue of IDH1 identified in

majority (>70%) of grades II and III astrocytomas and oligodendrogliomas, as well as in secondary GBMs that

developed from these lower grade lesions. Mutation analysis of closely related IDH2 revealed mutations of IDH2

residue R172, with most mutations occurring in tumors lacking IDH1 mutations. Tumors with IDH1 or IDH2 mutations

have distinctive genetic and clinical characteristics, and patients with such tumors have a better outcome than those

with wild type IDH genes.

Mutations in IDH1/2 are detected by DNA sequencing procedures. The limit of detection of standard bidirectional

sequencing is approximately 20-25%. In order to increase assay sensitivity tumor enrichment must be performed by

manual microdissection when tumor cells in the block constitute less than 50% of nucleated cells.

FDA COMMENT: The above data are not to be construed as the results from a stand alone diagnostic test. This test

was developed and its performance characteristics determined by the

as required by CLIA '88 regulations. It has not been cleared or approved for specific uses by the US Food

and Drug Administration (FDA). The FDA has determined that such clearance or approval is not necessary. These

results are provided for informational purposes only, and should be interpreted only in the context of established

procedures and/or diagnostic criteria.

Electronically Signed Out

Senior Staff Pathologist

IDH2 Mutation Detection Assay

Date Ordered: **Date Reported:**

Interpretation

NEGATIVE - There is no evidence of IDH2 point mutation, as indicated by the absence of any nucleotide changes in

codon 172 of the IDH2 gene compared to the electropherogram of the reference normal sample (wild type).

Results-Comments

TEST DESCRIPTION: IDH2 Mutation Analysis

Test performed on DNA extracted from tumor paraffin block (C1)

H and E slide was examined and no microdissection was needed.

Surgical Pathology

Page 4 of 5

Mutation of IDH1 occurs early in glioma progression with somatic mutations of the R132 residue of IDH1 identified in

majority (>70%) of grades II and III astrocytomas and oligodendrogliomas, as well as in secondary GBMs that

developed from these lower grade lesions. Mutation analysis of closely related IDH2 revealed mutations of IDH2

residue R172, with most mutations occurring in tumors lacking IDH1 mutations. Tumors with IDH1 or IDH2 mutations

have distinctive genetic and clinical characteristics, and patients with such tumors have a better outcome than those

with wild type IDH genes.

[page 4 of 4]
Mutations in IDH1/2 are detected by DNA sequencing procedures. The limit of detection of standard bidirectional sequencing is approximately 20-25%. In order to increase assay sensitivity tumor enrichment must be performed by manual microdissection when tumor cells in the block constitute less than 50% of nucleated cells. FDA COMMENT: The above data are not to be construed as the results from a stand alone diagnostic test. This test was developed and its performance characteristics determined by the

as required by CLIA '88 regulations. It has not been cleared or approved for specific uses by the US Food and Drug Administration (FDA). The FDA has determined that such clearance or approval is not necessary. These results are provided for informational purposes only, and should be interpreted only in the context of established procedures and/or diagnostic criteria.

Electronically Signed Out

Senior Staff Pathologist

Intra-Operative Consultation

A. Brain, left occipital tumor, biopsy: Diffuse glioma (favor high histological grade). (1 block)
The cytological smears and frozen sections are performed at and the results are reported to the Physician of Record on

Staff Pathologist

Gross Description

A. Brain, left occipital, biopsy:

FIXATIVE: None

GENERAL: A 2 x 1.5 x 0.5 cm aggregate of three tan-pink to red, soft biopsy fragments, submitted for intraoperative

evaluation. Representative tissue is submitted for cytological smears and frozen sections.

SECTIONS: A1 - frozen section remnant; A2 - unfrozen tissue, entirely submitted.

B. Brain, left occipital, biopsy:

FIXATIVE: None

GENERAL: A 1.5 x 1.5 x 0.5 cm aggregate of four red-pink, soft biopsy fragments. Tissue is entirely submitted for

permanent sections following discussion with the surgeon.

SECTIONS: B1 - entirely submitted.

C. Brain, left occipital, excision biopsy:

FIXATIVE: Formalin

GENERAL: A 3.0 x 2.0 x 0.4 cm irregular portion of tan-pink brain tissue.

SECTIONS: C1-C3 - entirely submitted.

Microscopic Description

The frozen section diagnosis is confirmed on the permanent sections.

Surgical Pathology

Page 5 of 5

Source: NCI Genomic Data Commons file 7d37f302-be35-4f0d-b912-0f0b99ebe451 (TCGA-06-A5U0.53494270-D299-4D89-8C66-05C361CFFA90.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).